Gene-level copy-number profile of tumor specimen ALCH-AD3G-TTP1-A from ALCHEMIST case ALCH-AD3G, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 78.7 years (28,741 days).
Specimen ALCH-AD3G-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4e298527-db7f-47db-b34e-adfcfe1f9a55.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AD3G-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/6ed0f392-d654-4eea-933f-1e8a280948c2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 2,347; copy number 2: 53,204; copy number 3: 2,838; copy number 4: 4; copy number 6: 1; copy number 8: 1; copy number 14: 2.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:25,835,985–25,836,832, 1 gene (within-gene range 0–2): AL390198.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:43,053,191–43,076,943, 1 gene, copy number 8: CBS.
- chr21:43,107,942–43,168,646, 1 gene, copy number 14 (within-gene range 1–14): AP001631.2.
- chr21:43,159,066–43,172,805, 2 genes, copy number 6–14: AP001631.1, CRYAA.

Autosomal genes at a single copy (total copy number 1): 2,347. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
